Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GN-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT CERVICAL LYMPH NODES, LEVEL III TO V:
METASTATIC MELANOMA TO AT LEAST ONE OF TWO LYMPH NODES.
TUMOR DEPOSIT OF 30.0 MM (GROSS DESCRIPTION).
EXTRACAPSULAR EXTENSION PRESENT (A COMPLETELY REPLACED LYMPH NODE IS NOT RULED OUT).
- (B) HIGHEST LEVEL III LYMPH NODE:
One lymph node negative for melanoma (0/1).

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Cervical lymph node
077.0
JAO 4/4/13

GROSS DESCRIPTION

(A) RIGHT CERVICAL LYMPH NODES, LEVELS III-V, PROTOCOL, PROTOCOL - A portion of fibroadipose tissue (10.0 x 4.5 x 2.0 cm) containing multiple nodes ranging up to 3.0 cm in greatest dimension. The largest node has solid, tan-white cut surfaces suspicious for tumor with possible surrounding skeletal muscle. Sections of the largest node are submitted to the tissue bank under sterile and non-sterile conditions. Representative sections of the suspicious node are submitted. The remaining nodes are entirely submitted.

SECTION CODE: A1, two possible nodes; A2, one possible node, bisected; A3, A4, representative sections of grossly suspicious node with possible surrounding skeletal muscle.

(B) HIGHEST LEVEL III NODE - Two fragments of fibroadipose tissue (2.0 x 1.5 x 1.0 cm in aggregate). Entirely submitted in B.

CLINICAL HISTORY

None given.

SNOMED CODES

T-C4000, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

This modified report is being issued to report additional specimens.

Addendum completed by

The specimen was reviewed at Dr. request. Additional examination of the peritumoral adipose tissue revealed multiple small, negative lymph nodes. Therefore, the diagnosis is:

DIAGNOSIS

- (A) RIGHT CERVICAL LYMPH NODES, LEVEL III TO V:
METASTATIC MELANOMA TO AT LEAST ONE OF TWENTY-FOUR LYMPH NODES (1/24).
TUMOR DEPOSIT OF 30.0 MM (GROSS DESCRIPTION).
EXTRACAPSULAR EXTENSION PRESENT
An area of matted lymph nodes is not ruled out.
- (B) HIGHEST LEVEL III LYMPH NODE:
One lymph node negative for melanoma (0/1).

GROSS DESCRIPTION

(A) RIGHT CERVICAL LYMPH NODES, LEVELS III-V, PROTOCOL, PROTOCOL - A portion of fibroadipose tissue (10.0 x 4.5 x 2.0 cm) containing multiple nodes ranging up to 3.0 cm in greatest dimension. The largest node has solid, tan-white cut surfaces suspicious for tumor with possible surrounding skeletal muscle. Sections of the largest node are submitted to the tissue bank under sterile and non-sterile conditions. Representative sections of the suspicious node are submitted. The remaining nodes are entirely submitted.

SECTION CODE: A1, two possible nodes; A2, one possible node, bisected; A3, A4, representative sections of grossly suspicious node with possible surrounding skeletal muscle,
Additional grossing: A5, one lymph node trisected; A6, four possible lymph nodes entirely submitted; A7, four lymph nodes entirely submitted; A8, five lymph nodes entirely submitted; A9, four lymph nodes entirely submitted; A10, four possible lymph nodes entirely submitted.

(B) HIGHEST LEVEL III NODE - Two fragments of fibroadipose tissue (2.0 x 1.5 x 1.0 cm in aggregate). Entirely submitted in B.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	W 12/20/12	Yes	No
H/P-NA Discrepancy			✓

Source: NCI Genomic Data Commons file 09ecc627-606e-496c-b7d3-70d0acb5964b (TCGA-D3-A5GN.67484CF7-02EB-460F-B604-17FB1CFA0BAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).